CPTAC case C3N-03456 — Floor of mouth — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ce10e6ca-05e1-4495-a3e6-868d375207ca

Demographics
Sex at birth: male; Race: white; Year of birth: 1953; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Floor of mouth, NOS; Age at diagnosis: 64.7 years (23,616 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,748 days (4.8 years); Progression or recurrence: no; Days to last follow up: 1,748 days (4.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 22; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 446 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 677 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 1,069 days (2.9 years); Disease response: Tumor Free; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 1,069 days (2.9 years); Disease response: Complete Response; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 1,426 days (3.9 years); Disease response: Tumor Free; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 1,748 days (4.8 years); Disease response: Tumor Free; Karnofsky performance status: 50; ECOG performance status: 3.

Other clinical attributes
- Weight: 88 kg; Height: 186 cm; BMI: 25.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 41; Cigarettes per day: 20; Tobacco smoking onset year: 1976; Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Exposure duration years: 46; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03456-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 273 mg; Time between excision and freezing: 8 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03456-21: Section location: Floor of Mouth; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-03456-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Time between excision and freezing: 8 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03456-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -2 days; Method of sample procurement: Blood Draw.
